Somatic mutation profile of tumor specimen MMRF_1735_1_BM_CD138pos (aliquot MMRF_1735_1_BM_CD138pos_T1_KBS5U_L04793) from MMRF case MMRF_1735, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.5 years (23,572 days).
Specimen MMRF_1735_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 335ffb70-4f2a-4b28-8941-4a1e2d332ad2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1735_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1735_1_PB_Whole_C3_KBS5U_L04805; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7faac8cd-942f-483c-8e54-bf46f79103a3

The open-access MAF lists 112 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 29, Silent 15, Intron 8, 5'UTR 4, 5'Flank 4, Frame Shift Del 3, Nonsense Mutation 2, RNA 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 189/375 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs761238221, CM065956, COSV55941839, COSV99710512; called by muse, mutect2, varscan2
- CDH10 | c.2062C>G p.R688G | Missense Mutation (SNP) | VAF 93/149 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV52589706; called by muse, mutect2, varscan2
- COL6A6 | c.5215C>T p.R1739* | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as rs370896099; called by muse, mutect2, varscan2
- COL9A3 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs757192189, COSV58983170; called by muse, mutect2, varscan2
- CSHL1 | c.461T>C p.M154T (on ENST00000309894 / NM_022581.3; = p.M60T on NM_001318.4) | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746946203, COSV99367890; called by muse, mutect2, varscan2
- DRG2 | c.280T>C p.F94L | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99854770; called by muse, mutect2, varscan2
- GABBR2 | c.1808G>T p.G603V | Missense Mutation (SNP) | VAF 55/324 reads (17%) | SIFT tolerated (0.94); PolyPhen probably damaging (1); catalogued as rs1564031721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPCL2 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as rs373693703; called by muse, mutect2
- HNRNPUL2 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 140/281 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs761865412, COSV57131802; called by muse, mutect2, varscan2
- IGHV2-70 | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs181122105; called by muse, varscan2
- IGKV3-20 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs537123757; called by muse, mutect2, varscan2
- IGLV3-25 | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs369304140; called by muse, varscan2
- IGLV3-25 | c.197T>A p.I66K | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs182651541; called by muse, varscan2
- IGLV3-25 | c.313T>A p.Y105N | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs779833481; called by muse, varscan2
- MROH2A | c.3415G>A p.V1139M | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1016334204; called by muse, mutect2, varscan2
- PATJ | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV57164847; called by muse, mutect2, varscan2
- PCDHB8 | c.937T>G p.F313V | Missense Mutation (SNP) | VAF 67/405 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs781933599; called by muse, mutect2, varscan2
- PDILT | c.1680G>T p.E560D | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); catalogued as rs778257621; called by muse, mutect2, varscan2
- PKHD1 | c.3728C>T p.T1243M | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as rs774865280; called by muse, mutect2
- PLXNA4 | c.5518C>A p.H1840N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs752209974; called by muse, mutect2, varscan2
- SBK1 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.044); catalogued as rs917820504; called by muse, mutect2, varscan2
- SPEG | c.3944C>T p.P1315L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs746765446; called by muse, mutect2, varscan2
- STAT5B | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1177773526, COSV53183835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS35L | c.1039G>C p.A347P | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99221206; called by muse, mutect2, varscan2
- ZMYND8 | c.1624C>T p.P542S (on ENST00000311275 / NM_001363741.2; = p.P562S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.145); catalogued as rs749490002; called by muse, mutect2, varscan2
- ADAMTS2 | c.3357C>A p.F1119L | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- BNC2 | c.2660T>C p.L887P | Missense Mutation (SNP) | VAF 198/435 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- C11orf95 | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- DUSP26 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L4A | c.697T>G p.Y233D | Missense Mutation (SNP) | VAF 200/623 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- H4C11 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- HERC1 | c.2322T>G p.S774R | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, varscan2
- IFT80 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 198/330 reads (60%) | called by muse, mutect2, varscan2
- IGLV3-25 | c.70A>C p.T24P | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, varscan2
- LPA | c.4093G>T p.V1365F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); called by muse, mutect2
- MFGE8 | c.967T>C p.Y323H | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- OR1Q1 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PWWP2A | c.1227A>C p.K409N | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- RYR1 | c.13569G>T p.K4523N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SH3RF2 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK2 | c.1437C>A p.N479K | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SLC6A19 | c.308T>A p.V103E | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, varscan2
- TNS3 | c.2077del p.L693Wfs*13 | Frame Shift Del (DEL) | VAF 45/154 reads (29%) | called by mutect2, pindel, varscan2
- TXNDC5 | c.989del p.N330Ifs*11 | Frame Shift Del (DEL) | VAF 99/241 reads (41%) | called by mutect2, pindel, varscan2
- VPS39 | c.319del p.Q107Kfs*34 (on ENST00000348544 / NM_001301138.2; = p.Q96Kfs*34 on NM_015289.5) | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- ZMAT1 | c.1801dup p.S601Kfs*3 | Frame Shift Ins (INS) | VAF 145/173 reads (84%) | called by mutect2, varscan2
- ZNF629 | c.784T>A p.Y262N | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF726 | c.2066T>C p.F689S | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP10A | c.1512C>T p.R504= | Silent (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- ATP7B | c.4305C>T p.S1435= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs771736533, COSV54435524; called by muse, mutect2, varscan2
- CDRT15L2 | c.198G>T p.S66= | Silent (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- CHPF | c.2223T>C p.S741= | Silent (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1590G>A p.E530= | Silent (SNP) | VAF 47/91 reads (52%) | catalogued as rs1397776106, COSV100561278; called by muse, mutect2, varscan2
- IGLV3-25 | c.69G>A p.L23= | Silent (SNP) | VAF 54/112 reads (48%) | catalogued as rs546527918; called by muse, varscan2
- IGLV4-60 | c.159C>A p.I53= | Silent (SNP) | VAF 83/164 reads (51%) | catalogued as rs188129839; called by muse, mutect2, varscan2
- KLK10 | c.465C>T p.A155= | Silent (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- LYST | c.7237C>T p.L2413= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV67705831; called by muse, mutect2, varscan2
- MEFV | c.63C>T p.F21= | Silent (SNP) | VAF 63/152 reads (41%) | called by muse, mutect2, varscan2
- NHLRC1 | c.405T>C p.C135= | Silent (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- PDILT | c.1068C>T p.Y356= | Silent (SNP) | VAF 56/111 reads (50%) | catalogued as rs745328107, COSV56703483; called by muse, mutect2, varscan2
- RETN | c.66C>T p.C22= | Silent (SNP) | VAF 82/238 reads (34%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.241C>T p.L81= | Silent (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- TTC28 | c.2919C>T p.Y973= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs761158695, COSV67422188; called by muse, mutect2, varscan2
- ADAMTS3 | c.*1931A>G | 3'UTR (SNP) | VAF 104/113 reads (92%) | catalogued as COSV99711772; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.*4000A>T | 3'UTR (SNP) | VAF 43/63 reads (68%) | called by muse, mutect2, varscan2
- ADGRG2 | c.305-94A>G | Intron (SNP) | VAF 45/45 reads (100%) | called by muse, mutect2, varscan2
- AP000311.1 | c.-16A>G | 5'UTR (SNP) | VAF 61/99 reads (62%) | called by muse, mutect2, varscan2
- AP000311.1 | c.-106A>G | 5'UTR (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- B4GALT6 | c.*1267T>G | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021300 G>A | 5'Flank (SNP) | VAF 51/120 reads (43%) | called by muse, mutect2, varscan2
- BHLHE40 | c.*673_*699del | 3'UTR (DEL) | VAF 70/140 reads (50%) | called by mutect2, pindel, varscan2
- BRAF | c.1861+194C>T | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, varscan2
- BTBD1 | c.*90T>C | 3'UTR (SNP) | VAF 15/84 reads (18%) | catalogued as rs553935846; called by muse, mutect2, varscan2
- CYP11A1 | c.*143C>T | 3'UTR (SNP) | VAF 59/159 reads (37%) | called by muse, mutect2, varscan2
- ERFE | c.*1690C>G | 3'UTR (SNP) | VAF 32/64 reads (50%) | called by muse, varscan2
- EXOC5 | c.*2156T>A | 3'UTR (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- FAM83H | c.*1077G>T | 3'UTR (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- FKBP15 | c.*2831C>T | 3'UTR (SNP) | VAF 59/259 reads (23%) | called by muse, mutect2, varscan2
- GP2 | chr16:20309828 T>C | 3'Flank (SNP) | VAF 44/86 reads (51%) | called by muse, mutect2, varscan2
- GXYLT2 | c.*239A>G | 3'UTR (SNP) | VAF 60/200 reads (30%) | catalogued as rs1313986302; called by muse, mutect2
- LAMC3 | c.*919C>A | 3'UTR (SNP) | VAF 64/232 reads (28%) | called by muse, mutect2, varscan2
- LIFR | c.*4282A>G | 3'UTR (SNP) | VAF 106/165 reads (64%) | called by muse, mutect2, varscan2
- LTB | c.163-149C>G | Intron (SNP) | VAF 84/174 reads (48%) | catalogued as COSV53000289, COSV53002609; called by muse, varscan2
- LTBP1 | c.*570C>T | 3'UTR (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- MALSU1 | c.*385C>T | 3'UTR (SNP) | VAF 29/106 reads (27%) | called by muse, mutect2, varscan2
- MAP3K7CL | c.371-15855C>T | Intron (SNP) | VAF 87/269 reads (32%) | called by muse, mutect2, varscan2
- MAPKAPK5 | chr12:111841898 G>A | 5'Flank (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851126 T>A | 5'Flank (SNP) | VAF 90/199 reads (45%) | catalogued as rs569234583; called by muse, varscan2
- NRG3 | c.824-191930C>T | Intron (SNP) | VAF 19/42 reads (45%) | catalogued as rs201815957, COSV64548840; called by muse, mutect2, varscan2
- OR2L5 | c.*6C>T | 3'UTR (SNP) | VAF 188/418 reads (45%) | catalogued as rs185180614; called by muse, mutect2, varscan2
- PEA15 | c.*1237A>G | 3'UTR (SNP) | VAF 34/50 reads (68%) | called by muse, mutect2, varscan2
- PEG10 | c.*172C>T | 3'UTR (SNP) | VAF 178/612 reads (29%) | called by muse, mutect2, varscan2
- PHEX | c.*199C>T | 3'UTR (SNP) | VAF 41/45 reads (91%) | called by muse, mutect2, varscan2
- PILRB | c.-634G>A | 5'UTR (SNP) | VAF 18/26 reads (69%) | catalogued as rs1389562793; called by muse, mutect2
- PRSS35 | c.*61C>T | 3'UTR (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- REG3G | c.*205T>G | 3'UTR (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- RHPN1 | c.*95T>C | 3'UTR (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- RNASE10 | c.-17C>T | 5'UTR (SNP) | VAF 95/235 reads (40%) | called by muse, mutect2, varscan2
- RPL7A | c.495+81A>G | Intron (SNP) | VAF 57/281 reads (20%) | called by muse, mutect2, varscan2
- SEMA3D | c.*2390T>G | 3'UTR (SNP) | VAF 44/135 reads (33%) | called by muse, mutect2, varscan2
- SERBP1 | c.*577_*579del | 3'UTR (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel
- SERPINH1P1 | n.1240C>A | RNA (SNP) | VAF 36/136 reads (26%) | called by muse, varscan2
- SYNDIG1 | c.*155C>G | 3'UTR (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- TMBIM6 | c.690+188del | Intron (DEL) | VAF 17/29 reads (59%) | catalogued as rs1475661238; called by mutect2, varscan2
- TOX4 | c.*2216C>T | 3'UTR (SNP) | VAF 5/57 reads (9%) | catalogued as rs948980332; called by muse, mutect2
- TRIM64B | c.*420G>A | 3'UTR (SNP) | VAF 35/289 reads (12%) | catalogued as rs1321422903; called by mutect2, varscan2
- TSPEAR | c.1566+2220G>C | Intron (SNP) | VAF 47/196 reads (24%) | called by muse, mutect2, varscan2
- VWC2L | c.*344T>G | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- Vault | n.29C>T | RNA (SNP) | VAF 80/119 reads (67%) | catalogued as rs947770228; called by muse, mutect2, varscan2
- ZNF606 | chr19:58007474 G>T | 5'Flank (SNP) | VAF 59/163 reads (36%) | called by muse, mutect2, varscan2
- ZNF747 | c.*1790C>T | 3'UTR (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
